Somatic mutation profile of tumor specimen 0DTTXF from CCDI case PBCJYF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Choroid plexus carcinoma; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 3.3 years (1,204 days).
Specimen 0DTTXF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03ee2b6a-df87-47a5-95a9-45cca360b675.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTTXA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfba6013-5547-4724-a31c-f7e645e2a050

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Intron 2, RNA 1, 5'UTR 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX5 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 446/638 reads (70%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.85); catalogued as rs771424855; called by muse, mutect2, varscan2
- CD34 | c.1114G>C p.G372R | Missense Mutation (SNP) | VAF 384/1295 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60411597; called by muse, mutect2, varscan2
- GDE1 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 305/401 reads (76%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs200327001, COSV62059097; called by muse, mutect2, varscan2
- GYS2 | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 555/1736 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760594068; called by muse, mutect2, varscan2
- MAGEB3 | c.158A>T p.K53M | Missense Mutation (SNP) | VAF 123/698 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.919); catalogued as COSV64397248; called by muse, mutect2, varscan2
- MAL | c.110T>G p.V37G | Missense Mutation (SNP) | VAF 607/808 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59431136; called by muse, mutect2, varscan2
- SLC43A3 | c.881A>C p.Y294S | Missense Mutation (SNP) | VAF 62/887 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs768560650; called by muse, mutect2
- SPEN | c.599G>C p.R200P | Missense Mutation (SNP) | VAF 794/927 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65364915, COSV65365127; called by muse, mutect2, varscan2
- ACSS3 | c.929T>G p.I310S | Missense Mutation (SNP) | VAF 248/762 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AOC2 | c.1990A>C p.T664P (on ENST00000253799 / NM_009590.4; = p.T637P on NM_001158.5) | Missense Mutation (SNP) | VAF 80/798 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- CAPZA3 | c.326T>G p.I109S | Missense Mutation (SNP) | VAF 730/1873 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- COL6A5 | c.7750A>G p.K2584E (on ENST00000312481; = p.K2580E on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 226/1627 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- IL2 | c.390G>C p.E130D | Missense Mutation (SNP) | VAF 538/1290 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRK2 | c.4526T>C p.L1509P | Missense Mutation (SNP) | VAF 398/1323 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- MYRIP | c.1097C>T p.T366I | Missense Mutation (SNP) | VAF 681/934 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR2J3 | c.583A>G p.T195A | Missense Mutation (SNP) | VAF 63/921 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2
- SHKBP1 | c.321_322del p.R108Sfs*72 | Frame Shift Del (DEL) | VAF 150/227 reads (66%) | called by mutect2, varscan2
- SYNE1 | c.4280T>C p.V1427A (on ENST00000367255 / NM_182961.4; = p.V1434A on NM_033071.3) | Missense Mutation (SNP) | VAF 652/1004 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- TMEM132D | c.1751T>C p.V584A | Missense Mutation (SNP) | VAF 353/830 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- USP14 | c.635A>C p.Q212P | Missense Mutation (SNP) | VAF 592/808 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VAV1 | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 242/347 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CERS5 | c.303+42G>A | Intron (SNP) | VAF 369/914 reads (40%) | catalogued as rs757353977; called by muse, mutect2, varscan2
- EXOSC10 | c.1880-64T>C | Intron (SNP) | VAF 34/247 reads (14%) | called by muse, mutect2, varscan2
- OLFM1 | c.-25G>A | 5'UTR (SNP) | VAF 68/92 reads (74%) | catalogued as rs762499441; called by muse, mutect2
- RPL6P21 | n.178A>T | RNA (SNP) | VAF 24/498 reads (5%) | called by muse, mutect2
- ZNF740 | c.*5364C>A | 3'UTR (SNP) | VAF 107/228 reads (47%) | called by muse, mutect2, varscan2
